MMRF case MMRF_1391 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7d0ffbcb-83fd-4bb1-8ef4-f2a6fbf1862a

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.4 years (23,871 days); ISS stage: II; Days to last known disease status: 1,031 days (2.8 years); Days to last follow up: 1,031 days (2.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 148 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 161 days; Days to treatment end: 161 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 162 days; Days to treatment end: 162 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1,026 days (2.8 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,031.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -19 (ECOG 1): M Protein 3.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 118 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.727 mg/dL; Immunoglobulin G 34.4 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.49 g/L; Beta 2 Microglobulin 2.32 µg/mL; Lactate Dehydrogenase 4.2 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.18 mmol/L; Albumin 32 g/L; Total Protein 8.2 g/dL; Glucose 4.57 mmol/L; C-Reactive Protein 0.18 mg/dL.
- Day 87 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.977 mg/dL; Immunoglobulin G 8.1 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.51 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 58.3 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.38 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 4.95 mmol/L.
- Day 183 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.088 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.512 mg/dL; Immunoglobulin G 4.88 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 1.86 µg/mL; Lactate Dehydrogenase 3.63 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.91 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 4.51 mmol/L.
- Day 262 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.96 mg/dL; Immunoglobulin G 7.62 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.46 g/L; Beta 2 Microglobulin 1.53 µg/mL; Lactate Dehydrogenase 3.7 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 4.84 mmol/L.
- Day 402 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.18 mg/dL; Immunoglobulin G 6.92 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.3 g/L; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 87 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 3.91 mmol/L.
- Day 458 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.81 mg/dL; Immunoglobulin G 6.51 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 4.02 mmol/L.
- Day 518 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.84 mg/dL; Immunoglobulin G 5.98 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 3.73 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 87 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 5.9 g/dL; Glucose 3.52 mmol/L.
- Day 609 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.4 mg/dL; Immunoglobulin G 7.87 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 105 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 3.85 mmol/L.
- Day 693 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.33 mg/dL; Immunoglobulin G 7.72 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 3.08 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 98 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 4.51 mmol/L.
- Day 784 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.26 mg/dL; Immunoglobulin G 7.61 g/L; Immunoglobulin A 0.75 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 3.92 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 104 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.13 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 4.57 mmol/L.
- Day 861 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.75 mg/dL; Immunoglobulin G 7.32 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.43 mmol/L; Albumin 37 g/L; Total Protein 6.1 g/dL; Glucose 3.85 mmol/L.
- Day 959 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.04 mg/dL; Immunoglobulin G 8.14 g/L; Immunoglobulin A 0.76 g/L; Immunoglobulin M 0.29 g/L; Lactate Dehydrogenase 3.27 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 6.4 g/dL; Glucose 4.73 mmol/L.
- Day 1,025 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.57 mg/dL; Immunoglobulin G 7.23 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 3.82 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 93 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 5.7 g/dL; Glucose 4.51 mmol/L.

Other clinical attributes
- Day -19: Weight: 53 kg; Height: 170 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: female.

Biospecimens (3 samples)
- Sample MMRF_1391_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -19 days.
- Sample MMRF_1391_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -19 days.
- Sample MMRF_1391_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 262 days.
